CCDI case PBBJVU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/059e1f9c-1358-411b-9187-5e561b0b3590

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,399 days).

Biospecimens (3 samples)
- Sample 0DAAZ7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAAZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAAZL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
